Somatic mutation profile of tumor specimen MP2PRT-PAPVNZ-TMP1-A (aliquot MP2PRT-PAPVNZ-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPVNZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,041 days).
Specimen MP2PRT-PAPVNZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75724840-1ee1-4899-aefb-de80a8112de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVNZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVNZ-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96dc6ba1-2b6a-43c3-adc4-00396f157ffc

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXO1 | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 26/842 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65426970; called by muse, mutect2
- COL24A1 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs759165044, COSV100993810; called by muse, mutect2, varscan2
- HEXD | c.1357C>T p.P453S (on ENST00000327949 / NM_001369487.1; = p.T482= on NM_173620.3) | Missense Mutation (SNP) | VAF 19/746 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1275918684; called by muse, mutect2
- LIG4 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as rs747189258, COSV63597490; called by muse, mutect2, varscan2
- LONRF1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV68036646; called by muse, mutect2
- MUC17 | c.12086C>T p.S4029F | Missense Mutation (SNP) | VAF 20/652 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs942601509; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHC3 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1306633539, COSV65441293; called by muse, mutect2
- SLC17A8 | c.1646G>C p.G549A | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV60124008; called by muse, mutect2
- ZFHX4 | c.8291C>T p.P2764L | Missense Mutation (SNP) | VAF 176/395 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.796); catalogued as rs755319742, COSV51468474; called by muse, mutect2, varscan2
- ACP1 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL6A3 | c.4592C>G p.S1531C | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DDX31 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GALNT13 | c.1348A>C p.N450H | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- HMGCS1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 131/357 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGHV3-43 | chr14:106470260 del GTGTATCTTTTGCACAGTAATACAAGGCG | Missense Mutation (DEL) | VAF 32/238 reads (13%) | called by pindel, varscan2*
- KHDC4 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- MAMLD1 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 29/654 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2
- MAP3K2 | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MOSPD1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MROH9 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- NOS3 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 148/404 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- PRIMPOL | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 18/547 reads (3%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.521); called by muse, mutect2
- SMIM27 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 96/281 reads (34%) | called by muse, varscan2
- SORBS1 | c.997G>A p.E333K (on ENST00000361941 / NM_001034954.2; = p.E169K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- UCHL1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF852 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ABCA12 | c.6168C>T p.F2056= (on ENST00000272895 / NM_173076.3; = p.F1738= on NM_015657.3) | Silent (SNP) | VAF 50/253 reads (20%) | called by muse, mutect2, varscan2
- FLNA | c.6777C>T p.F2259= (on ENST00000369850 / NM_001110556.2; = p.F2251= on NM_001456.3) | Silent (SNP) | VAF 94/321 reads (29%) | catalogued as COSV100775193, COSV61036478; called by muse, mutect2, varscan2
- HBB | c.183G>T p.V61= | Silent (SNP) | VAF 181/467 reads (39%) | catalogued as COSV58942883; called by muse, mutect2, varscan2
- ITPRID1 | c.735C>T p.A245= | Silent (SNP) | VAF 32/496 reads (6%) | catalogued as rs757417828, COSV100086039; called by muse, mutect2
- MSL3 | c.216G>A p.V72= | Silent (SNP) | VAF 24/343 reads (7%) | called by muse, mutect2
- OR2A2 | c.912C>T p.L304= | Silent (SNP) | VAF 113/321 reads (35%) | called by muse, mutect2, varscan2
- PDE11A | c.84C>T p.V28= | Silent (SNP) | VAF 110/333 reads (33%) | catalogued as COSV61773701; called by muse, mutect2, varscan2
- PSMB2 | c.420C>T p.L140= | Silent (SNP) | VAF 15/301 reads (5%) | called by muse, mutect2
- WDR91 | c.1518C>T p.N506= | Silent (SNP) | VAF 23/349 reads (7%) | catalogued as rs376395238; called by muse, mutect2
